Surgical pathology report (de-identified scan), TCGA case TCGA-HB-A5W3, project TCGA-SARC (Sarcoma), tissue source site University of North Carolina, specimen TCGA-HB-A5W3-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Pancreas, biopsy

- Positive for malignancy, consistent with leiomyosarcoma.
- No pancreatic tissue is present.

B: Adrenal artery margin, biopsy

- Peripheral nerve and ganglion with no evidence of malignancy.

C: Left kidney, spleen, distal pancreas, adrenal, excision

Histologic tumor type/subtype: leiomyosarcoma (see comment)

Histologic grade (if applicable): high grade

Tumor size (greatest dimension): 26 cm in greatest dimension

Extent of tumor invasion: Tumor appears to arise from the renal pelvis and focally invades renal parenchyma. The tumor displaces but does not invade adrenal gland, spleen, or pancreas. However, there is invasion of periadrenal adipose tissue.

Histologic assessment of surgical margins: Ureteral, renal vascular, pancreatic, and soft tissue margins are free of tumor.

Regional lymph nodes: 2 lymph nodes are present and show no evidence of metastatic leiomyosarcoma (0/2).

Distant metastases: not present

Lymphovascular invasion: present

Non-lesional kidney: interstitial fibrosis and chronic inflammation

AJCC Staging:

pT3

pN0

ICD-O-3
Leiomyosarcoma NOS 8890/3
Site: path Renal pelvis C65.9
C&F Retroperitoneum C48.0
4/2 3/18/13

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

COMMENT:

Immunohistochemical stains were performed on block C3 with

[page 2 of 3]
appropriate controls. The tumor cells are diffusely positive for SMA and focally positive for desmin. They are negative for CD34, CD 117, S-100, AE1/AE3, RCC, and CD10. The findings support the above diagnosis. Dr. has reviewed selected slides and concurs with the diagnosis.

Intraoperative Consult Diagnosis:

An intraoperative consultation was requested by

FSA1: Pancreas, biopsy

- Malignant spindle cell neoplasm present, differential includes sarcomatous variant of renal cell carcinoma or primary sarcoma, defer to permanents for final classification.

FSB1: Adrenal artery margin, biopsy

- Peripheral nerve and ganglion, no tumor seen

Clinical History:

-year-old female with 26 cm left renal mass with pulmonary mets who undergoes debulking.

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "pancreas biopsy." The specimen is received fresh and placed in formalin. The specimen consists of a 0.2 x 0.2 x 0.2 cm fragment of yellow/tan soft tissue, previously frozen in toto and submitted in block FSA1,

Container B is additionally labeled "adrenal artery margin." The specimen is received fresh and placed in formalin and consists of a 1 x 0.5 x 0.5 cm fragment of red/tan soft tissue, previously frozen in toto and submitted in block FSB1,

Container C is additionally labeled "left kidney, spleen, distal pancreas, adrenal." The specimen is received fresh and placed in formalin. Overall, it holds a 2,700 gram, 27 x 17.5 x 11 cm mass composed of kidney, adrenal, tail of pancreas, and spleen.

The kidney is 20 x 17.5 x 11 cm. The renal parenchyma is markedly distorted and compressed by a 26 x 17.3 x 10 cm solid,

[page 3 of 3]
tan-white, whorled and firm mass that exhibits large amounts of hemorrhage and necrosis concentrated primarily in the superior half. The superior half of the mass is more fleshy and markedly softened. The renal parenchyma is markedly compressed around the periphery of the mass and is comprised of tan parenchyma with a cortex/medulla, 0.7cm/2 cm.

The mass abuts the renal pelvis but does not appear to extend through it and is 2.5 cm from the ureteral margin and 3 cm from the renal vascular margin. The superior pole of the kidney is not identified and the mass appears to extend into the superior perinephric fat.

The mass abuts the tail of the pancreas (7.5 x 4.3 x 1.8 cm) and grossly appears to infiltrate it. The mass is 3.9 cm from the pancreatic margin. The pancreatic parenchyma is lobulated and grossly unremarkable, otherwise.

The adrenal gland (4 x 2 x 0.4 cm) abuts, but does not grossly appear to be involved by the mass.

The spleen (11.5 x 7 x 2.9 cm) is freely movable above the mass, exhibits unremarkable hilar fatty tissue, a smooth, glistening, pink capsule with a 3 x 1.5 cm area of subcapsular hemorrhage. The cut surface is brown/pink and unremarkable with no nodules identified.

There are two surface defects located on the superior/medial aspect of the mass which are inked yellow and orange.

Sections of the tumor were submitted to Cytogenetics,

Block summary:

- C1 - ureteral/renal vasculature margins
- C2-C3 - mass with respect to kidney
- C4 - mass with respect to renal pelvis
- C5 - kidney
- C6 - pancreatic margin (inked blue, en face)
- C7 - mass with respect to pancreas
- C8 - mass with respect to adrenal gland
- C9-C11 - mass, representative
- C12 - mass with respect to overlying soft tissue
- C13,C14 - surface defects
- C15 - spleen

Source: NCI Genomic Data Commons file b15cf405-5ff5-4df3-94fa-8942ba07d49b (TCGA-HB-A5W3.0D3D6C3C-9344-456A-9AAC-CDF0833713F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).